Somatic mutation profile of tumor specimen MP2PRT-PATBSE-TBP1-A (aliquot MP2PRT-PATBSE-TBP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PATBSE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,394 days).
Specimen MP2PRT-PATBSE-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62232277-feef-4c60-aef8-5e1b13b248a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBSE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBSE-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/243881de-06c6-4a24-8ba6-99a0d4e300c9

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 4, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 65/328 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, varscan2
- DLGAP4 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 59/532 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs906950306, COSV59414912; called by muse, mutect2, varscan2
- LRP4 | c.3388G>A p.A1130T | Missense Mutation (SNP) | VAF 36/365 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.903); catalogued as rs142904009; called by muse, mutect2, varscan2
- MTTP | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 64/561 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs761103347, COSV99645030; called by muse, mutect2, varscan2
- TRMT44 | c.399_400insCCCG p.E134Pfs*46 | Frame Shift Ins (INS) | VAF 109/846 reads (13%) | called by mutect2, pindel, varscan2
- ABCA8 | c.2568T>C p.S856= | Silent (SNP) | VAF 68/383 reads (18%) | called by muse, mutect2, varscan2
- KDR | c.12G>A p.K4= | Silent (SNP) | VAF 131/890 reads (15%) | catalogued as rs772252781; called by muse, mutect2, varscan2
- SASH1 | c.660G>A p.S220= | Silent (SNP) | VAF 80/449 reads (18%) | catalogued as rs756344953; called by muse, mutect2, varscan2
- ZFHX2 | c.3243G>A p.P1081= | Silent (SNP) | VAF 46/518 reads (9%) | catalogued as rs549697582; called by muse, mutect2
- ZSWIM2 | c.210G>A p.P70= | Silent (SNP) | VAF 37/209 reads (18%) | catalogued as rs765189432, COSV54574784; called by muse, mutect2, varscan2
- CCDC83 | c.794+1267G>T | Intron (SNP) | VAF 49/331 reads (15%) | called by muse, mutect2, varscan2
